Somatic mutation profile of tumor specimen 3329b802-e49f-4494-b645-868a25 (aliquot 3329b802-e49f-4494-b645-868a25_D6_1) from CPTAC case 01BR033, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 40.0 years (14,599 days).
Specimen 3329b802-e49f-4494-b645-868a25: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebc75681-cbe1-4d0c-8626-100bf96c2204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0ab89209-3cf4-4082-a5d8-684c84 (Blood Derived Normal), aliquot 0ab89209-3cf4-4082-a5d8-684c84_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fd98ad1-bed4-4e99-919b-d234f05122b6

The open-access MAF lists 94 somatic variants for this specimen: 72 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 15, Frame Shift Del 4, In Frame Del 3, Intron 2, Splice Site 2, 5'Flank 2, RNA 2, Frame Shift Ins 2, Splice Region 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.3307C>A p.Q1103K | Missense Mutation (SNP) | VAF 172/694 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV52471521; called by muse, mutect2, varscan2
- ADAMTS17 | c.3154G>T p.D1052Y | Missense Mutation (SNP) | VAF 155/700 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99171796; called by muse, mutect2, varscan2
- AKAP4 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV62074130; called by mutect2, varscan2
- DNAH11 | c.5692G>A p.G1898R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767246053, COSV100177331, COSV60960557; called by muse, mutect2, varscan2
- DPPA3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 130/566 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as rs752611710; called by muse, mutect2, varscan2
- FAM47C | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs782152014, COSV63724731; called by muse, mutect2, varscan2
- IGFN1 | c.3644C>A p.T1215N (on ENST00000295591 / NM_001367841.1; = p.T3672N on NM_001164586.2) | Missense Mutation (SNP) | VAF 40/680 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV99812386; called by muse, mutect2
- ITGB4 | c.1178C>G p.T393R | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs752599095, COSV52322640; called by muse, mutect2, varscan2
- LRFN4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs758732410, COSV58922899; called by muse, mutect2
- MYBPH | c.342C>T p.A114= | Splice Region (SNP) | VAF 42/268 reads (16%) | catalogued as rs1269087901; called by muse, mutect2, varscan2
- OR51I2 | c.740C>G p.A247G | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100413379; called by mutect2, varscan2
- PHLDA1 | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs975531956; called by muse, mutect2, varscan2
- PPP2R1A | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs148604195, COSV59043195; called by muse, mutect2, varscan2
- PTCH1 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 148/582 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV59481818; called by muse, mutect2, varscan2
- RPGR | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1435213397, COSV58839048; called by muse, mutect2, varscan2
- SH2B1 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as rs369173659; called by muse, mutect2, varscan2
- STK19 | c.848G>C p.R283P (on ENST00000375333 / NM_032454.1; = p.R279P on NM_004197.1) | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64692585; called by muse, mutect2
- TBC1D5 | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772208813; called by muse, mutect2, varscan2
- TMCO3 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 261/1159 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64807595; called by muse, mutect2, varscan2
- TTC14 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs763786849, COSV56012287; called by muse, mutect2
- UBQLN2 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 78/391 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57740233; called by muse, mutect2, varscan2
- WIPF1 | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1372180396, COSV99768466; called by muse, mutect2
- ABL1 | c.3349C>A p.L1117I | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACVR1C | c.300_304+26del p.X100_splice | Splice Site (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.1626_1627dup p.Q543Pfs*48 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | called by pindel, varscan2
- ADH1C | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- AL645922.1 | c.1530C>A p.F510L | Missense Mutation (SNP) | VAF 242/1110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BCL9L | c.3548C>G p.S1183C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- CENPE | c.3041G>T p.G1014V | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CFAP97D1 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CLEC11A | c.307_310del p.T103Lfs*36 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, pindel, varscan2
- COL5A3 | c.801C>G p.N267K | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFR | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 94/593 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); called by mutect2, varscan2
- ESR1 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FOLH1 | c.1969A>C p.N657H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- GCNT4 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GNB1L | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GZMK | c.576_597delinsGGTC p.F192_C199delinsLV | In Frame Del (DEL) | VAF 47/245 reads (19%) | called by pindel, varscan2*
- H3-3B | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- HBA2 | c.221T>A p.V74E | Missense Mutation (SNP) | VAF 145/825 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- IFT140 | c.2266_2274del p.R756_P758del | In Frame Del (DEL) | VAF 35/270 reads (13%) | called by mutect2, pindel, varscan2
- ITGB1 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IWS1 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KRTAP4-12 | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- LENG8 | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MED16 | c.2480G>A p.C827Y | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH2A | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2
- MTUS2 | c.4053C>A p.Y1351* (on ENST00000612955 / NM_001366650.1; = p.Y330* on NM_015233.6) | Nonsense Mutation (SNP) | VAF 117/931 reads (13%) | called by muse, mutect2, varscan2
- NOXA1 | c.783_790delinsCGA p.S262Dfs*34 | Frame Shift Del (DEL) | VAF 25/225 reads (11%) | called by pindel, varscan2*
- ONECUT3 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- PALB2 | c.3302_3303dup p.V1103Afs*4 | Frame Shift Ins (INS) | VAF 104/506 reads (21%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.716C>A p.A239E (on ENST00000259318 / NM_001136562.3; = p.A470E on NM_007203.5) | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PDE1B | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- PEG3 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 20/569 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2
- PIAS3 | c.246del p.G83Afs*5 | Frame Shift Del (DEL) | VAF 94/436 reads (22%) | called by mutect2, pindel, varscan2
- PLD4 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2
- PLXNA2 | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RECQL5 | c.2312G>C p.R771T | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.187); called by muse, mutect2
- RETREG1 | c.476C>G p.S159C (on ENST00000306320 / NM_001034850.2; = p.S18C on NM_019000.4) | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMIM9 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS1 | c.2712C>A p.N904K | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SPANXB1 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 68/1081 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2
- STRN3 | c.1528del p.Q510Kfs*12 (on ENST00000357479 / NM_001083893.2; = p.Q426Kfs*12 on NM_014574.4) | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- TATDN1 | c.517-1G>A p.X173_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- THOC1 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- THUMPD3 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTYH2 | c.931A>T p.T311S | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WIZ | c.3598A>T p.I1200F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ZBED6 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZGRF1 | c.3279G>C p.E1093D | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF226 | c.2046_2062delinsTG p.W682_M688delinsCV | In Frame Del (DEL) | VAF 21/163 reads (13%) | called by pindel, varscan2*
- ZNF638 | c.4258T>A p.S1420T | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- A2ML1 | c.2982G>A p.L994= | Silent (SNP) | VAF 49/261 reads (19%) | called by muse, mutect2, varscan2
- BRPF3 | c.957C>T p.A319= | Silent (SNP) | VAF 139/471 reads (30%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.666C>T p.F222= | Silent (SNP) | VAF 96/556 reads (17%) | catalogued as rs957903827, COSV59261727; called by muse, mutect2, varscan2
- CDK13 | c.744C>T p.S248= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs1447156355; called by muse, mutect2, varscan2
- CELSR2 | c.3921G>A p.E1307= | Silent (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- DSG3 | c.336A>G p.T112= | Silent (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- LGALSL | c.51C>T p.G17= | Silent (SNP) | VAF 6/162 reads (4%) | catalogued as COSV53230399; called by muse, mutect2
- MYT1L | c.1725T>C p.A575= | Silent (SNP) | VAF 18/504 reads (4%) | catalogued as rs1393252502; called by muse, mutect2
- NACAD | c.333C>T p.L111= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs1176703393, COSV71989379; called by muse, mutect2, varscan2
- PTPRO | c.1386C>T p.S462= | Silent (SNP) | VAF 117/620 reads (19%) | catalogued as rs1565672449; called by muse, mutect2, varscan2
- S1PR2 | c.234C>T p.S78= | Silent (SNP) | VAF 42/706 reads (6%) | catalogued as rs757513633, COSV58485325; called by muse, mutect2
- SON | c.4614T>C p.N1538= | Silent (SNP) | VAF 80/333 reads (24%) | called by muse, mutect2, varscan2
- TBC1D9B | c.3717C>T p.T1239= (on ENST00000356834 / NM_198868.3; = p.T1222= on NM_015043.4) | Silent (SNP) | VAF 91/221 reads (41%) | catalogued as rs1474118908; called by muse, mutect2, varscan2
- TBX18 | c.1692G>A p.T564= | Silent (SNP) | VAF 45/239 reads (19%) | catalogued as rs757361472, COSV63736613, COSV63737169; called by muse, mutect2, varscan2
- TMEM158 | c.585G>T p.L195= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CMAHP | n.649C>T | RNA (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- CYP2B7P | n.1085C>G | RNA (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- DNAH10 | c.9645-892C>A | Intron (SNP) | VAF 15/409 reads (4%) | catalogued as rs927205188; called by muse, mutect2
- IFRD2 | chr3:50292826 C>G | 5'Flank (SNP) | VAF 25/674 reads (4%) | catalogued as COSV57115526; called by muse, mutect2
- NRXN1 | c.4039-30405T>A | Intron (SNP) | VAF 45/242 reads (19%) | called by muse, mutect2, varscan2
- PPM1N | chr19:45502222 T>A | 3'Flank (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- ZNF467 | chr7:149777681 G>A | 5'Flank (SNP) | VAF 146/598 reads (24%) | catalogued as rs374482349; called by muse, mutect2, varscan2
